Somatic mutation profile of tumor specimen TCGA-DA-A1I0-06A (aliquot TCGA-DA-A1I0-06A-11D-A20D-08) from TCGA case TCGA-DA-A1I0, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 63.9 years (23,346 days).
Specimen TCGA-DA-A1I0-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de2b7283-35ac-455f-9325-ebb68db08ebe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DA-A1I0-10B (Blood Derived Normal), aliquot TCGA-DA-A1I0-10B-01D-A20D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f31f935a-a41f-4046-8b9d-34174ec89d5f

The open-access MAF lists 601 somatic variants for this specimen: 393 protein-altering or splice-affecting, 196 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 342, Silent 196, Nonsense Mutation 35, Splice Site 8, Frame Shift Del 3, 3'UTR 3, RNA 3, Intron 3, In Frame Del 2, 5'Flank 2, Nonstop Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 117/211 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 118/210 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CLCN1 | c.854G>A p.G285E | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs150885084, CM980361; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1283G>A p.G428E (on ENST00000373993 / NM_138932.2; = p.G420E on NM_014576.4) | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs1404517565, COSV50958219; called by muse, mutect2, varscan2
- A1CF | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.073); catalogued as rs574044306, COSV50966965; called by muse, mutect2, varscan2
- ABCA9 | c.2936G>A p.R979Q | Missense Mutation (SNP) | VAF 38/181 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.427); catalogued as rs747525085, COSV60625079; called by muse, mutect2, varscan2
- ABCC10 | c.1579C>T p.L527F (on ENST00000372530 / NM_001198934.2; = p.L484F on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs573202769, COSV55088069; called by muse, mutect2, varscan2
- ABCC6 | c.3041C>T p.A1014V | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs150583228; called by muse, mutect2, varscan2
- ABCC8 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.79); PolyPhen benign (0.013); catalogued as rs1448146101, COSV56850824; called by muse, mutect2, varscan2
- ABCC9 | c.3061G>A p.E1021K | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs749668601, COSV53967755, COSV99688007; called by muse, mutect2, varscan2
- ABCG1 | c.439G>A p.G147S | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.954); catalogued as rs764667661, COSV59204501; called by muse, mutect2, varscan2
- ADAM11 | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs184207190, COSV52346439; called by muse, mutect2, varscan2
- ADAM28 | c.1114C>T p.P372S | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56100772; called by muse, varscan2
- ADAMTS18 | c.2354C>T p.S785F | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs865821391, COSV51410950; called by muse, mutect2, varscan2
- ADCY10 | c.2683C>T p.R895C | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.959); catalogued as rs779053477, COSV63240979; called by muse, mutect2, varscan2
- ADGRF1 | c.1475C>T p.P492L | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV51945644; called by muse, mutect2, varscan2
- ADGRF1 | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 60/129 reads (47%) | SIFT tolerated (0.75); PolyPhen benign (0.084); catalogued as rs769420876, COSV51945657; called by muse, mutect2, varscan2
- ADGRV1 | c.11688G>A p.M3896I | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV67985610; called by muse, mutect2
- AFDN | c.4711C>T p.Q1571* | Nonsense Mutation (SNP) | VAF 7/24 reads (29%) | catalogued as COSV60045249; called by muse, mutect2, varscan2
- AFF1 | c.3190C>T p.R1064C | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs867215989, COSV57119983; called by muse, mutect2, varscan2
- AFMID | c.98T>C p.V33A | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.219); catalogued as COSV56959779; called by muse, mutect2, varscan2
- AHSG | c.34C>T p.Q12* | Nonsense Mutation (SNP) | VAF 13/49 reads (27%) | catalogued as rs752791757, COSV56607856; called by muse, mutect2, varscan2
- AIM2 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 52/127 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.429); catalogued as COSV63699826; called by muse, mutect2, varscan2
- AKAP13 | c.533G>A p.R178K | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.089); catalogued as rs1397935483, COSV63457821; called by muse, mutect2, varscan2
- AKAP6 | c.1526G>A p.R509Q | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs775238509, COSV55214420; called by muse, mutect2, varscan2
- AMBN | c.473G>A p.G158E | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.012); catalogued as rs754791754, COSV59826184; called by muse, mutect2, varscan2
- AMN | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.61); PolyPhen benign (0.073); catalogued as rs766554192, COSV54486878; called by muse, mutect2
- ANK3 | c.6079G>A p.D2027N | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as COSV55058689; called by muse, mutect2, varscan2
- APOL1 | c.25G>A p.V9I | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs1028842274, COSV59869046; called by muse, mutect2, varscan2
- ARHGEF15 | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV62725265; called by muse, mutect2, varscan2
- ARHGEF5 | c.4750C>T p.R1584* | Nonsense Mutation (SNP) | VAF 27/220 reads (12%) | catalogued as rs750003677, COSV50209207, COSV99283095; called by muse, mutect2, varscan2
- ARMC4 | c.3125G>A p.R1042K | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59464011; called by muse, mutect2, varscan2
- ARMC4 | c.1748C>T p.A583V | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as COSV59464024, COSV59467580; called by muse, mutect2, varscan2
- ARMCX2 | c.1543C>T p.R515C | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV57530163; called by muse, mutect2, varscan2
- ARNTL2 | c.313A>T p.M105L | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV53825883; called by muse, mutect2, varscan2
- ASB15 | c.1574C>A p.P525Q | Missense Mutation (SNP) | VAF 80/131 reads (61%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.655); catalogued as COSV51926103; called by muse, mutect2, varscan2
- ASPRV1 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57228148; called by muse, mutect2, varscan2
- ASZ1 | c.802C>T p.H268Y | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV52913075; called by muse, mutect2, varscan2
- ATG14 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0.054); catalogued as COSV55956635; called by muse, mutect2, varscan2
- ATN1 | c.1684G>A p.G562S | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated, low confidence (0.22); PolyPhen probably damaging (0.954); catalogued as COSV63111102; called by muse, mutect2, varscan2
- ATP12A | c.2897G>A p.R966K | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT tolerated (0.96); PolyPhen benign (0.01); catalogued as COSV54516524; called by muse, mutect2, varscan2
- ATXN1 | c.176G>A p.R59K | Missense Mutation (SNP) | VAF 104/311 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.315); catalogued as rs1257578125, COSV55217051; called by muse, mutect2, varscan2
- BMP3 | c.433A>C p.S145R | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as COSV51085098; called by muse, mutect2, varscan2
- BRIP1 | c.3737C>T p.P1246L | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs876660074, COSV51999912, COSV52009645; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BUB1B | c.736G>A p.G246R | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55012834; called by muse, mutect2, varscan2
- C14orf39 | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV58782152; called by muse, mutect2, varscan2
- C6 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs267600638, COSV54704649; called by muse, mutect2, varscan2
- C8A | c.1294G>A p.G432S | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.057); catalogued as rs781576042, COSV63484187; called by muse, mutect2, varscan2
- CABYR | c.*140+1G>A | Splice Site (SNP) | VAF 23/77 reads (30%) | catalogued as rs772312679, COSV59111051; called by muse, mutect2, varscan2
- CCDC178 | c.162G>T p.K54N | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as COSV55774688; called by muse, mutect2, varscan2
- CCDC18 | c.2174T>C p.V725A (on ENST00000343253 / NM_001306076.1; = p.V726A on NM_206886.4) | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58143714; called by muse, mutect2, varscan2
- CCL7 | c.193A>C p.I65L | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.874); catalogued as COSV52337051; called by muse, mutect2, varscan2
- CD300A | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60410167; called by muse, mutect2, varscan2
- CD68 | c.1043C>T p.P348L | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.598); catalogued as COSV51510870; called by muse, mutect2
- CDR1 | c.723G>A p.W241* | Nonsense Mutation (SNP) | VAF 60/113 reads (53%) | catalogued as rs770637010, COSV65164283; called by muse, mutect2, varscan2
- CEACAM16 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.136); catalogued as COSV69186869; called by muse, mutect2, varscan2
- CELSR1 | c.5278G>T p.E1760* | Nonsense Mutation (SNP) | VAF 34/103 reads (33%) | catalogued as COSV53090611; called by muse, mutect2, varscan2
- CELSR3 | c.8443G>T p.E2815* | Nonsense Mutation (SNP) | VAF 21/77 reads (27%) | catalogued as COSV50862272; called by muse, mutect2, varscan2
- CENPU | c.617C>T p.S206L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs557667316, COSV55656911; called by muse, mutect2, varscan2
- CER1 | c.357G>A p.M119I | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.04); catalogued as rs751789872, COSV66602840, COSV66603341; called by muse, mutect2, varscan2
- CFAP251 | c.3235G>A p.G1079S | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as rs765528971, COSV56610652; called by muse, mutect2, varscan2
- CFAP47 | c.5099G>A p.W1700* | Nonsense Mutation (SNP) | VAF 20/50 reads (40%) | catalogued as COSV57973974; called by muse, mutect2, varscan2
- CFH | c.2029G>A p.E677K | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.012); catalogued as rs757407902, COSV66408723; called by muse, mutect2, varscan2
- CGNL1 | c.2073G>A p.M691I | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV55565714; called by muse, mutect2, varscan2
- CHD5 | c.388-1G>A p.X130_splice | Splice Site (SNP) | VAF 8/30 reads (27%) | catalogued as COSV52415093; called by muse, mutect2, varscan2
- CHKB | c.545C>T p.T182I | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); catalogued as COSV56416763; called by muse, mutect2, varscan2
- CHL1 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56592948; called by muse, mutect2, varscan2
- CHRNA9 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as COSV59574564; called by muse, mutect2, varscan2
- CLEC2B | c.85C>T p.R29* | Nonsense Mutation (SNP) | VAF 15/44 reads (34%) | catalogued as rs771674688, COSV57308579, COSV99947008; called by muse, mutect2, varscan2
- CLMP | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 18/63 reads (29%) | catalogued as rs756079825, COSV71649777; called by muse, mutect2, varscan2
- CNTN5 | c.1136C>T p.S379F | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.702); catalogued as rs866845091, COSV54279011; called by muse, mutect2, varscan2
- COL10A1 | c.379G>A p.G127R | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54573051; called by muse, mutect2, varscan2
- COL17A1 | c.2702-1G>A p.X901_splice | Splice Site (SNP) | VAF 21/77 reads (27%) | catalogued as COSV62226858; called by muse, mutect2, varscan2
- COL1A1 | c.2450C>T p.P817L | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as CD165124, COSV56805206; called by muse, mutect2, varscan2
- COL1A1 | c.1538C>T p.S513F | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.244); catalogued as COSV56805218; called by muse, mutect2, varscan2
- COL21A1 | c.1670G>A p.G557E | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55163281; called by muse, mutect2, varscan2
- COL28A1 | c.1615G>A p.E539K | Missense Mutation (SNP) | VAF 67/136 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV68082183; called by muse, mutect2, varscan2
- COL4A4 | c.1625G>A p.G542E | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61632436; called by muse, mutect2, varscan2
- COL4A5 | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as CD993253, COSV60362046; called by muse, mutect2, varscan2
- COL7A1 | c.5200G>A p.G1734S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60395562; called by muse, mutect2, varscan2
- COL8A1 | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV53734800; called by muse, mutect2, varscan2
- CPED1 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 25/260 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as COSV60002662, COSV60017710; called by muse, mutect2
- CPED1 | c.2056-1G>A p.X686_splice | Splice Site (SNP) | VAF 24/194 reads (12%) | catalogued as rs1349297351, COSV60002683; called by muse, mutect2, varscan2
- CRYBG1 | c.4462G>A p.E1488K | Missense Mutation (SNP) | VAF 43/195 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64812273; called by muse, mutect2, varscan2
- CSDE1 | c.1960T>G p.F654V (on ENST00000358528 / NM_001007553.3; = p.F623V on NM_007158.6) | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV54747179, COSV54761429; called by muse, mutect2, varscan2
- CSMD3 | c.8192G>A p.G2731E | Missense Mutation (SNP) | VAF 90/170 reads (53%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.608); catalogued as COSV52186418; called by muse, mutect2, varscan2
- CSMD3 | c.7955C>T p.T2652M (on ENST00000297405 / NM_001363185.1; = p.T2548M on NM_052900.3) | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757060591, COSV52186438, COSV52276704, COSV99835151; called by muse, mutect2
- CSPP1 | c.949C>T p.R317C (on ENST00000676605; = p.R276C on NM_024790.6) | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.111); catalogued as rs114953032, COSV51584805; called by muse, mutect2, varscan2
- CTAGE1 | c.1255C>T p.Q419* | Nonsense Mutation (SNP) | VAF 19/87 reads (22%) | catalogued as COSV66943487; called by muse, mutect2, varscan2
- CTAGE1 | c.200G>A p.S67N | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV66943493; called by muse, mutect2, varscan2
- CTNNA3 | c.721G>A p.V241I | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV65584314; called by muse, mutect2, varscan2
- CUZD1 | c.1786C>T p.R596W | Missense Mutation (SNP) | VAF 53/274 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs139868556; called by muse, mutect2, varscan2
- CYP2C9 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV53248894; called by muse, mutect2, varscan2
- CYP2J2 | c.1498C>T p.P500S | Missense Mutation (SNP) | VAF 86/460 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV64606175; called by muse, mutect2, varscan2
- DAGLA | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV57196239; called by muse, mutect2, varscan2
- DCC | c.1124A>T p.D375V | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59103710; called by muse, mutect2, varscan2
- DCC | c.1958G>A p.G653E | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59087685; called by muse, mutect2, varscan2
- DENND3 | c.1538C>G p.P513R | Missense Mutation (SNP) | VAF 60/296 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV52802548; called by muse, mutect2, varscan2
- DHX35 | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs780595580, COSV52670380; called by muse, mutect2, varscan2
- DIDO1 | c.1702C>T p.P568S | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as COSV56622809, COSV99824642; called by muse, mutect2, varscan2
- DMGDH | c.1807G>A p.D603N | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV54863862; called by muse, mutect2, varscan2
- DNAH11 | c.1063C>T p.P355S | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as COSV60956526; called by muse, mutect2, varscan2
- DNAH11 | c.9043C>T p.P3015S | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV60956532; called by muse, mutect2, varscan2
- DNAH9 | c.5564C>T p.T1855I | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52350494; called by muse, mutect2, varscan2
- DOCK9 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.953); catalogued as COSV59638248; called by mutect2, varscan2
- DPEP3 | c.1049G>A p.G350E | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52051376; called by muse, mutect2, varscan2
- DPP10 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as rs1278855062, COSV59687953; called by muse, mutect2, varscan2
- DRD5 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.092); catalogued as COSV58578068; called by muse, mutect2
- DSG3 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs774736138, COSV57124224; called by muse, mutect2, varscan2
- EDRF1 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV61763255; called by muse, mutect2, varscan2
- EFR3A | c.2375C>T p.P792L | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV54457562, COSV54460854; called by muse, mutect2, varscan2
- EIF4A2 | c.687G>A p.M229I | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.383); catalogued as COSV56215365; called by muse, mutect2, varscan2
- EMID1 | c.743C>T p.P248L | Missense Mutation (SNP) | VAF 25/37 reads (68%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.999); catalogued as rs780589393, COSV61829500; called by muse, mutect2, varscan2
- ENPP4 | c.758C>T p.S253F | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.155); catalogued as COSV58089026; called by muse, mutect2, varscan2
- ERBB4 | c.1714C>T p.P572S | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.045); catalogued as COSV53534194; called by muse, mutect2, varscan2
- ERICH3 | c.1597G>A p.D533N | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs867745110, COSV58603843; called by muse, mutect2, varscan2
- ERV3-1 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1333108987, COSV51427798; called by muse, mutect2, varscan2
- ESPNL | c.1238G>A p.G413E | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs779351650, COSV58034701; called by muse, mutect2, varscan2
- FAM120B | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 71/281 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV53004081; called by muse, mutect2, varscan2
- FAM177B | c.185C>T p.S62F | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV62601131; called by muse, mutect2, varscan2
- FAM227B | c.727C>T p.R243* | Nonsense Mutation (SNP) | VAF 16/72 reads (22%) | catalogued as rs762968186, COSV54805848; called by muse, mutect2, varscan2
- FAM47A | c.1474C>T p.H492Y | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.607); catalogued as COSV60496914; called by muse, varscan2
- FAM71D | c.230C>T p.S77F | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV61294731; called by muse, varscan2
- FBXO43 | c.264T>A p.N88K | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV71054014; called by muse, mutect2, varscan2
- FCRL2 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 31/212 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.241); catalogued as rs368999734; called by muse, mutect2, varscan2
- FCRL6 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 53/112 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.056); catalogued as COSV58941226; called by muse, mutect2, varscan2
- FER1L6 | c.3882G>A p.W1294* | Nonsense Mutation (SNP) | VAF 36/238 reads (15%) | catalogued as COSV67550043; called by muse, mutect2, varscan2
- FGD5 | c.1172G>A p.G391E | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.255); catalogued as rs764968788, COSV53243052; called by muse, mutect2, varscan2
- FGF4 | c.569G>A p.G190E | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866953016, COSV51449981; called by muse, mutect2, varscan2
- FGF9 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as COSV66644695; called by muse, mutect2, varscan2
- FIG4 | c.2398G>A p.E800K | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV57787760; called by muse, mutect2, varscan2
- FLNC | c.5702A>C p.K1901T | Missense Mutation (SNP) | VAF 19/210 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57956194; called by muse, mutect2
- FLYWCH1 | c.1750C>T p.P584S (on ENST00000253928 / NM_001308068.2; = p.P583S on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV54146027; called by muse, mutect2, varscan2
- FMN2 | c.1841C>T p.S614L | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV60431159; called by muse, mutect2, varscan2
- FMNL2 | c.1060G>A p.D354N | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV56495387; called by muse, mutect2
- FMO3 | c.1302G>A p.M434I | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as rs72549332, CM004474; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FNIP2 | c.1640T>C p.V547A | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.508); catalogued as COSV52440034; called by muse, mutect2, varscan2
- FRAS1 | c.4007C>T p.S1336L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs746766578, COSV53625416; called by muse, mutect2, varscan2
- GABRA2 | c.1083G>A p.M361I | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV62915135; called by muse, mutect2, varscan2
- GABRA3 | c.263-1G>A p.X88_splice | Splice Site (SNP) | VAF 32/49 reads (65%) | catalogued as COSV64799050; called by muse, mutect2, varscan2
- GALNT17 | c.1772G>A p.W591* | Nonsense Mutation (SNP) | VAF 21/70 reads (30%) | catalogued as COSV61163207; called by muse, varscan2
- GOLGB1 | c.5415G>A p.M1805I | Missense Mutation (SNP) | VAF 60/223 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV61466058; called by muse, mutect2, varscan2
- GPC5 | c.1563G>A p.W521* | Nonsense Mutation (SNP) | VAF 21/97 reads (22%) | catalogued as rs763208703, COSV65600001; called by muse, mutect2, varscan2
- GPHA2 | c.175G>C p.G59R | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51210329; called by muse, mutect2, varscan2
- GPLD1 | c.665T>G p.M222R | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV57757209; called by muse, mutect2, varscan2
- GPR158 | c.1839G>A p.M613I | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as COSV66270683; called by muse, mutect2, varscan2
- GPR75 | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 12/55 reads (22%) | catalogued as rs376986894; called by muse, mutect2, varscan2
- GRAMD4 | c.1085-1G>A p.X362_splice | Splice Site (SNP) | VAF 6/62 reads (10%) | catalogued as COSV63030347; called by muse, mutect2
- GRIN3A | c.2033G>A p.W678* | Nonsense Mutation (SNP) | VAF 36/116 reads (31%) | catalogued as COSV62453995; called by muse, mutect2, varscan2
- GTDC1 | c.1198C>T p.P400S (on ENST00000344850 / NM_001354361.1; = p.P315S on NM_024659.6 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53995161; called by muse, mutect2, varscan2
- HAVCR1 | c.992C>T p.S331L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as rs1202177280, COSV59399962; called by muse, mutect2, varscan2
- HCRTR1 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200024185, COSV65485556; called by muse, mutect2, varscan2
- HCRTR2 | c.1184C>T p.T395I | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1015940761, COSV63795987; called by muse, mutect2, varscan2
- HELB | c.893A>T p.Y298F | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56073850; called by muse, mutect2, varscan2
- HLA-DQA1 | c.507T>A p.H169Q | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as COSV58238906; called by muse, mutect2, varscan2
- HS3ST4 | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 74/268 reads (28%) | catalogued as rs267604480, COSV58812934, COSV58826059; called by muse, mutect2, varscan2
- HSPA6 | c.640A>T p.I214F | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV59061124; called by muse, mutect2, varscan2
- HSPB1 | c.536T>A p.I179N | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV50349231; called by mutect2, varscan2
- IARS1 | c.1831C>T p.P611S | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65115267; called by muse, mutect2, varscan2
- IBSP | c.565G>A p.G189S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.334); catalogued as rs771317223, COSV56895796; called by muse, mutect2, varscan2
- IFI30 | c.668C>T p.T223I | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.035); catalogued as rs775483671, COSV69576571; called by muse, mutect2, varscan2
- IGF1R | c.3989G>A p.G1330D | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV51289604; called by muse, mutect2, varscan2
- IGHM | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as rs782008458; called by muse, mutect2
- IGHV3-21 | c.263C>T p.T88I | Missense Mutation (SNP) | VAF 84/358 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.433); catalogued as rs1213620167; called by muse, varscan2
- IGKV3-15 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as rs562860462; called by muse, mutect2, varscan2
- IGLV3-1 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as rs750241056; called by muse, mutect2, varscan2
- IL36B | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.961); catalogued as COSV52086453; called by muse, mutect2, varscan2
- ITGAD | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV66758154, COSV66759025; called by muse, mutect2, varscan2
- ITPK1 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50895636; called by muse, mutect2, varscan2
- KBTBD3 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1229989939, COSV73241421; called by muse, mutect2, varscan2
- KCNB2 | c.1969G>A p.E657K | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.049); catalogued as COSV73050366; called by muse, mutect2, varscan2
- KERA | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV57130737; called by muse, mutect2, varscan2
- KIAA0586 | c.3547C>T p.P1183S (on ENST00000619416 / NM_001244190.2; = p.P1122S on NM_014749.5) | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as COSV54176138; called by muse, mutect2, varscan2
- KIDINS220 | c.4385C>T p.S1462L | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.184); catalogued as COSV56753704; called by muse, mutect2, varscan2
- KLHDC7A | c.2129C>G p.T710R | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.165); catalogued as COSV68769236, COSV68769830; called by muse, mutect2, varscan2
- KMT2A | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV63286011; called by muse, mutect2, varscan2
- KRT77 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV59239843; called by muse, varscan2
- LAMA3 | c.9351+1G>A p.X3117_splice (on ENST00000313654 / NM_198129.4; = p.X1508_splice on NM_000227.6) | Splice Site (SNP) | VAF 7/58 reads (12%) | catalogued as rs1046313816, COSV52535030; called by muse, mutect2, varscan2
- LHCGR | c.263G>A p.R88K | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as COSV54297249, COSV99684215; called by muse, mutect2, varscan2
- LHX6 | c.983G>A p.G328E (on ENST00000373755 / NM_001242334.2; = p.G357E on NM_014368.5) | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as COSV61344654; called by muse, mutect2, varscan2
- LIPF | c.1179A>G p.I393M | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV53284109; called by muse, mutect2, varscan2
- LIPI | c.1301C>T p.S434F | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV60710154; called by muse, mutect2, varscan2
- LRFN2 | c.529C>T p.Q177* | Nonsense Mutation (SNP) | VAF 47/111 reads (42%) | catalogued as COSV57827683; called by muse, mutect2, varscan2
- LRP1B | c.12172G>A p.D4058N | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV67206505, COSV67283723; called by muse, mutect2, varscan2
- LRP1B | c.1294G>A p.D432N | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.395); catalogued as COSV67222349; called by muse, mutect2, varscan2
- LRRC27 | c.1250C>A p.P417Q | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV63997149; called by muse, mutect2, varscan2
- LRRC4 | c.361G>A p.G121S | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV50814052; called by muse, mutect2, varscan2
- LRRC43 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.04); catalogued as COSV60290093, COSV60293673; called by muse, mutect2, varscan2
- LRTM1 | c.967G>A p.G323R | Missense Mutation (SNP) | VAF 50/171 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV55540480; called by muse, mutect2, varscan2
- MACF1 | c.3290C>T p.T1097I | Missense Mutation (SNP) | VAF 31/140 reads (22%) | catalogued as COSV58374624; called by muse, mutect2, varscan2
- MAN2B1 | c.2960C>T p.P987L | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs373174565; called by muse, mutect2, varscan2
- MAP3K7CL | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.357); catalogued as COSV54509619, COSV54510297; called by muse, mutect2, varscan2
- MAP4K4 | c.971G>T p.S324I | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV56331532; called by muse, mutect2
- MAU2 | c.447C>A p.F149L | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.371); catalogued as COSV53235455; called by muse, mutect2, varscan2
- MBD5 | c.4183G>A p.G1395R | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV68695732, COSV68697111; called by muse, mutect2, varscan2
- ME1 | c.1516A>T p.I506F | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV63839353; called by muse, mutect2, varscan2
- MEP1A | c.1575G>A p.M525I | Missense Mutation (SNP) | VAF 31/248 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as COSV57921296; called by muse, mutect2, varscan2
- MET | c.2527C>T p.P843S | Missense Mutation (SNP) | VAF 61/114 reads (54%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV59261706; called by muse, mutect2, varscan2
- METTL8 | c.800C>T p.P267L | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769171322, COSV64549895; called by muse, mutect2, varscan2
- MICAL2 | c.4412G>A p.R1471Q | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.003); catalogued as rs543193412, COSV56286025; called by muse, mutect2, varscan2
- MIDEAS | c.2740C>T p.P914S | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as COSV54095062; called by muse, mutect2, varscan2
- MLF1 | c.467T>A p.I156N | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1286659605, COSV63033696; called by muse, mutect2, varscan2
- MLXIPL | c.2302T>G p.F768V | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as COSV57668252; called by muse, mutect2, varscan2
- MMP11 | c.574C>T p.H192Y | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53156310; called by muse, mutect2, varscan2
- MSL3 | c.877C>T p.P293S (on ENST00000312196 / NM_078629.4; = p.P127S on NM_006800.4) | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.294); catalogued as COSV56493336; called by muse, mutect2, varscan2
- MTCL1 | c.1138C>T p.R380W (on ENST00000306329 / NM_001378206.1; = p.R20W on NM_015210.4) | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60406272; called by muse, mutect2, varscan2
- MTMR9 | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 46/186 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.67); catalogued as rs144999294; called by muse, mutect2, varscan2
- MUC16 | c.37363G>A p.G12455R | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.3); catalogued as rs1233219263, COSV67467569; called by muse, mutect2, varscan2
- MUC16 | c.24675G>A p.W8225* | Nonsense Mutation (SNP) | VAF 15/42 reads (36%) | catalogued as COSV67467571; called by muse, mutect2, varscan2
- MUC5B | c.12083G>A p.W4028* | Nonsense Mutation (SNP) | VAF 9/49 reads (18%) | catalogued as COSV101500766; called by muse, mutect2, varscan2
- MUSK | c.2348C>T p.S783F | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51886633; called by muse, mutect2, varscan2
- MYBPC3 | c.2783C>T p.S928L | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as rs773819168, CM058262, COSV57027914; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH14 | c.3419C>T p.A1140V | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as COSV51818481; called by muse, mutect2, varscan2
- MYH2 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 49/245 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV55438753; called by muse, mutect2, varscan2
- MYL5 | c.53G>A p.R18K | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV58520005; called by muse, mutect2, varscan2
- MYO15A | c.383G>A p.S128N | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV52757030; called by muse, mutect2
- MYO15A | c.5762G>A p.R1921Q | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.826); catalogued as rs763685950, COSV52757036; called by muse, mutect2, varscan2
- MYO16 | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV51795368; called by muse, mutect2, varscan2
- NANOG | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 44/196 reads (22%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.986); catalogued as rs766569539, COSV57551446; called by muse, mutect2, varscan2
- NARS1 | c.688C>T p.L230F | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.744); catalogued as COSV56876919; called by muse, mutect2, varscan2
- NEK8 | c.1400G>A p.W467* | Nonsense Mutation (SNP) | VAF 47/169 reads (28%) | catalogued as COSV52045001; called by muse, mutect2, varscan2
- NF1 | c.7487C>T p.S2496F (on ENST00000358273 / NM_001042492.3; = p.S2475F on NM_000267.3) | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.55); catalogued as CX004454, COSV62196701; called by muse, mutect2, varscan2
- NFXL1 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV61199018; called by muse, mutect2, varscan2
- NID1 | c.2554G>A p.E852K | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.072); catalogued as COSV51620618; called by muse, mutect2, varscan2
- NLRP4 | c.1121C>T p.S374F | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as COSV56714129; called by muse, mutect2, varscan2
- NLRP8 | c.1639G>A p.G547R | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs199980675, COSV52582719, COSV52587771; called by muse, mutect2, varscan2
- NPAS4 | c.1597C>T p.P533S | Missense Mutation (SNP) | VAF 56/277 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV60650554; called by muse, mutect2, varscan2
- NPC1 | c.526C>A p.L176M | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.011); catalogued as COSV52580820; called by muse, mutect2, varscan2
- NPC1L1 | c.1530G>A p.M510I | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.023); catalogued as rs1468384; called by muse, mutect2, varscan2
- ODF2 | c.1720C>T p.L574F (on ENST00000434106 / NM_153433.2; = p.L550F on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV100654905, COSV63547165; called by muse, mutect2, varscan2
- OOSP2 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs140171460, COSV53928347, COSV99613480; called by muse, mutect2, varscan2
- OPN4 | c.171G>A p.W57* | Nonsense Mutation (SNP) | VAF 27/76 reads (36%) | catalogued as COSV54115226; called by muse, mutect2, varscan2
- OPRPN | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.737); catalogued as COSV68192932; called by muse, mutect2
- OR10J5 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs749659274, COSV58386147; called by muse, mutect2, varscan2
- OR13C8 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV58611226; called by muse, mutect2, varscan2
- OR1N1 | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV59195741; called by muse, mutect2, varscan2
- OR1N2 | c.757C>T p.L253F | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV65460661; called by muse, mutect2, varscan2
- OR2L3 | c.695G>A p.G232E | Missense Mutation (SNP) | VAF 106/225 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.434); catalogued as rs1173909196, COSV63455072; called by muse, varscan2
- OR2T4 | c.98C>T p.T33I | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV63544083, COSV63544305; called by muse, mutect2, varscan2
- OR4N2 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 67/504 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs866280852, COSV60050102; called by muse, mutect2, varscan2
- OR52A1 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.019); catalogued as COSV61092459; called by muse, mutect2, varscan2
- OR52K2 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 56/218 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.146); catalogued as COSV57835059; called by muse, mutect2, varscan2
- OR5T1 | c.740G>A p.R247K | Missense Mutation (SNP) | VAF 55/206 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as COSV57302767; called by muse, mutect2, varscan2
- OR6C75 | c.365T>A p.M122K | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV58552292; called by muse, mutect2
- OR8U1 | c.698G>A p.G233E | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100164153, COSV56414361; called by muse, mutect2, varscan2
- P4HA3 | c.722G>A p.G241E | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV59041976; called by muse, mutect2, varscan2
- PATJ | c.3007C>T p.P1003S | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as rs747595265, COSV57162595; called by muse, mutect2, varscan2
- PCDH15 | c.4580C>T p.P1527L | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.18); catalogued as COSV57267565, COSV57390652; called by muse, mutect2, varscan2
- PCDHA8 | c.2383C>T p.H795Y | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.001); catalogued as rs930917896, COSV65326752; called by muse, mutect2, varscan2
- PCK1 | c.180G>A p.M60I | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV60126631, COSV60128128; called by muse, mutect2, varscan2
- PCLO | c.4651G>A p.E1551K | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.298); catalogued as rs1390343890, COSV61632542; called by muse, mutect2, varscan2
- PDE3A | c.3304C>T p.Q1102* | Nonsense Mutation (SNP) | VAF 43/191 reads (23%) | catalogued as COSV100762880, COSV62973248; called by muse, mutect2, varscan2
- PER1 | c.2077C>T p.P693S | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.419); catalogued as COSV57919574; called by muse, mutect2, varscan2
- PHKA1 | c.2051G>A p.G684E | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.589); catalogued as COSV59805986; called by muse, mutect2, varscan2
- PIK3AP1 | c.1715C>T p.S572F | Missense Mutation (SNP) | VAF 81/344 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.549); catalogued as COSV59531245; called by muse, mutect2, varscan2
- PIN1 | c.61C>T p.R21* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as COSV56112693; called by muse, mutect2, varscan2
- PIWIL1 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.822); catalogued as COSV55346930; called by muse, mutect2, varscan2
- PKHD1L1 | c.2074G>A p.D692N | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV65743417; called by muse, mutect2, varscan2
- PKHD1L1 | c.5126C>T p.A1709V | Missense Mutation (SNP) | VAF 35/372 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as rs1367495389, COSV65743423; called by muse, mutect2, varscan2
- PKM | c.35T>A p.F12Y | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.39); catalogued as COSV58788547; called by muse, mutect2, varscan2
- PLA2G4F | c.1031G>A p.G344E | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV51827024; called by muse, mutect2, varscan2
- PLCB1 | c.2173C>T p.P725S | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62051758; called by muse, mutect2, varscan2
- PLCZ1 | c.1517C>T p.S506L | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV56853009; called by muse, mutect2, varscan2
- PLEK | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0.091); catalogued as COSV52251905; called by muse, mutect2, varscan2
- PLEKHG7 | c.1226G>A p.R409K | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV60821744; called by muse, mutect2, varscan2
- POLN | c.2066G>A p.G689E | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV67025385; called by muse, mutect2, varscan2
- POLQ | c.3118C>T p.R1040* | Nonsense Mutation (SNP) | VAF 13/65 reads (20%) | catalogued as rs764050733, COSV51752379; called by muse, mutect2, varscan2
- PPFIA4 | c.2066G>A p.R689Q (on ENST00000447715; = p.R690Q on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as rs1476254296, COSV55315286; called by muse, mutect2, varscan2
- PRAMEF17 | c.953G>A p.S318N | Missense Mutation (SNP) | VAF 57/281 reads (20%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.699); catalogued as COSV101068649; called by muse, mutect2, varscan2
- PRDM16 | c.1472C>T p.S491F | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV54591041; called by muse, mutect2, varscan2
- PRG3 | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54663582; called by muse, mutect2, varscan2
- PRKCH | c.1870C>T p.H624Y | Missense Mutation (SNP) | VAF 69/261 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs756851217, COSV60648379; called by muse, mutect2, varscan2
- PRSS37 | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.262); catalogued as COSV63339289; called by muse, mutect2, varscan2
- PTPRK | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 46/185 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV63887719; called by muse, mutect2, varscan2
- RAB5C | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV60525232; called by muse, mutect2, varscan2
- RALGPS1 | c.893C>T p.S298F | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV52222370; called by muse, mutect2, varscan2
- RASAL2 | c.2104C>T p.P702S | Missense Mutation (SNP) | VAF 51/113 reads (45%) | SIFT tolerated (0.89); PolyPhen benign (0.145); catalogued as COSV62714389; called by muse, mutect2, varscan2
- RELCH | c.3161C>T p.P1054L | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV56885831; called by muse, mutect2, varscan2
- RIF1 | c.6848C>T p.S2283F | Missense Mutation (SNP) | VAF 36/174 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV54617338; called by muse, mutect2, varscan2
- RLF | c.4607C>T p.A1536V | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65651915; called by muse, mutect2, varscan2
- RNF17 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV55040798; called by muse, mutect2, varscan2
- RNF26 | c.1297C>T p.L433F | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60990506; called by muse, mutect2, varscan2
- RP1 | c.5497G>A p.D1833N | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.344); catalogued as COSV55117212, COSV55123126; called by muse, mutect2, varscan2
- RPS6KA6 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as rs368124048; called by muse, mutect2, varscan2
- RRP1B | c.1670G>A p.G557E | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV61479129; called by muse, mutect2
- RSPH9 | c.246G>A p.W82* | Nonsense Mutation (SNP) | VAF 9/58 reads (16%) | catalogued as rs1469207335, COSV64664892; called by muse, mutect2
- RYR1 | c.8206G>A p.D2736N | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs867506234, COSV62097886; called by muse, mutect2, varscan2
- RYR2 | c.1627G>A p.G543R | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV63686852; called by muse, mutect2, varscan2
- S100A7L2 | c.274G>A p.G92R | Missense Mutation (SNP) | VAF 84/207 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV64195199, COSV64195417; called by muse, mutect2, varscan2
- SAMD9 | c.3188G>A p.G1063E | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.966); catalogued as COSV66075340; called by muse, mutect2, varscan2
- SCN3A | c.1417A>C p.S473R | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.731); catalogued as COSV51810424; called by muse, mutect2, varscan2
- SCN5A | c.5725C>T p.Q1909* (on ENST00000333535 / NM_198056.3; = p.Q1908* on NM_000335.5) | Nonsense Mutation (SNP) | VAF 19/102 reads (19%) | catalogued as COSV61124739; called by muse, mutect2, varscan2
- SCN9A | c.979G>A p.G327R | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV57610527; called by muse, mutect2, varscan2
- SDK1 | c.2599G>A p.G867R | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1205197141, COSV67364246; called by muse, mutect2, varscan2
- SEL1L2 | c.1867C>T p.P623S | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.048); catalogued as COSV53152519; called by muse, varscan2
- SEMA3D | c.703C>T p.H235Y | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.763); catalogued as rs748469336, COSV52393939; called by muse, mutect2, varscan2
- SEPHS1 | c.151C>T p.Q51* | Nonsense Mutation (SNP) | VAF 48/197 reads (24%) | catalogued as COSV59258518, COSV59259342; called by muse, mutect2, varscan2
- SERPINB11 | c.263G>A p.G88D | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs757240794, COSV66956706, COSV66956989; called by muse, mutect2, varscan2
- SERPINB3 | c.181C>T p.Q61* | Nonsense Mutation (SNP) | VAF 20/73 reads (27%) | catalogued as COSV52191721; called by muse, mutect2, varscan2
- SLC2A4 | c.1414C>T p.R472* | Nonsense Mutation (SNP) | VAF 99/357 reads (28%) | catalogued as COSV50300975; called by muse, mutect2, varscan2
- SLC36A3 | c.976T>C p.L326= | Splice Region (SNP) | VAF 20/65 reads (31%) | catalogued as COSV58856906; called by muse, mutect2, varscan2
- SLC4A3 | c.2627C>T p.A876V | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0.01); catalogued as rs760268231, COSV56093952; called by muse, mutect2, varscan2
- SLC7A3 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0.05); PolyPhen benign (0.055); catalogued as COSV53227526; called by muse, mutect2, varscan2
- SLC9C1 | c.3415G>A p.E1139K | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.006); catalogued as COSV59888351; called by muse, mutect2, varscan2
- SLIT2 | c.809T>C p.V270A | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.146); catalogued as COSV56573355; called by muse, mutect2, varscan2
- SLIT3 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs771927308, COSV60609085; called by muse, mutect2, varscan2
- SLITRK6 | c.1259G>A p.G420D | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68389826, COSV68390265; called by muse, mutect2, varscan2
- SMAD6 | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 45/187 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV56594955; called by muse, mutect2, varscan2
- SMARCC2 | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 24/114 reads (21%) | catalogued as COSV57218576, COSV57225072; called by muse, mutect2, varscan2
- SMC5 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs141003657; called by muse, mutect2, varscan2
- SNTB1 | c.1023G>A p.W341* | Nonsense Mutation (SNP) | VAF 48/223 reads (22%) | catalogued as COSV67326297; called by muse, mutect2, varscan2
- SPATA46 | c.668G>A p.W223* | Nonsense Mutation (SNP) | VAF 32/126 reads (25%) | catalogued as rs1295833143, COSV62635181; called by muse, mutect2, varscan2
- SPEN | c.7622C>T p.P2541L | Missense Mutation (SNP) | VAF 57/331 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV65362102; called by muse, mutect2, varscan2
- SPG11 | c.3538C>T p.P1180S | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55995169; called by muse, mutect2, varscan2
- SPHKAP | c.3109C>T p.L1037F | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV60868405, COSV60879780; called by muse, mutect2, varscan2
- SPOCK2 | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV58036544; called by muse, mutect2, varscan2
- SRD5A2 | c.631C>T p.L211F | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.025); catalogued as COSV51871609; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.44T>C p.L15P | Missense Mutation (SNP) | VAF 13/77 reads (17%) | PolyPhen possibly damaging (0.758); catalogued as rs1178394106, COSV59565745; called by muse, mutect2, varscan2
- SUB1 | c.377A>G p.K126R | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.025); catalogued as COSV54082684; called by muse, mutect2, varscan2
- SVEP1 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.393); catalogued as COSV57049393; called by muse, mutect2, varscan2
- SYK | c.1733G>A p.G578E | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65327359; called by muse, mutect2, varscan2
- TAS2R4 | c.663G>T p.Q221H | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.059); catalogued as rs771788898, COSV56093605; called by muse, mutect2, varscan2
- TATDN3 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 50/92 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as COSV65325284; called by muse, mutect2, varscan2
- TBPL1 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.633); catalogued as COSV52783755; called by muse, mutect2, varscan2
- TBX15 | c.1658G>A p.G553E (on ENST00000369429 / NM_001330677.2; = p.G447E on NM_152380.3) | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.448); catalogued as COSV52871397; called by muse, mutect2, varscan2
- TBX15 | c.571C>T p.P191S (on ENST00000369429 / NM_001330677.2; = p.P85S on NM_152380.3) | Missense Mutation (SNP) | VAF 33/220 reads (15%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.992); catalogued as rs1414082680, COSV52871415; called by muse, mutect2, varscan2
- TCHHL1 | c.767G>A p.G256E | Missense Mutation (SNP) | VAF 81/189 reads (43%) | SIFT tolerated (0.66); PolyPhen benign (0.005); catalogued as rs140526562; called by muse, mutect2, varscan2
- TDRD5 | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 71/162 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs867687242, COSV54242060; called by muse, mutect2, varscan2
- TEK | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 42/169 reads (25%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.793); catalogued as COSV66229066; called by muse, mutect2, varscan2
- TENM3 | c.2948C>T p.P983L | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV69308686; called by muse, mutect2
- TEX14 | c.2287G>A p.E763K (on ENST00000240361 / NM_001201457.2; = p.E757K on NM_031272.5) | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1285057092, COSV53617373; called by muse, mutect2, varscan2
- TMCC1 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as rs1223014685, COSV67873103; called by muse, mutect2, varscan2
- TNKS2 | c.1130C>T p.P377L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.147); catalogued as COSV65415605; called by muse, mutect2, varscan2
- TRERF1 | c.1448C>T p.P483L | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as rs748676426, COSV61671885; called by muse, mutect2, varscan2
- TRHR | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs750828177, COSV61234355; called by muse, mutect2, varscan2
- TRMT9B | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs192687145, COSV101501634; called by muse, mutect2, varscan2
- TRRAP | c.2165C>T p.S722F | Missense Mutation (SNP) | VAF 111/247 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs147405090, COSV62839126, COSV62849075; called by muse, mutect2, varscan2
- TSHR | c.1127A>T p.E376V | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.311); catalogued as COSV53320457; called by muse, mutect2, varscan2
- TTK | c.986C>T p.S329F | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.093); catalogued as COSV57883853; called by muse, mutect2
- TTN | c.3947G>A p.G1316E (on ENST00000591111; = p.G1270E on NM_003319.4) | Missense Mutation (SNP) | VAF 24/78 reads (31%) | PolyPhen probably damaging (1); catalogued as COSV60076081; called by muse, mutect2, varscan2
- TWF2 | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as rs765914663; called by muse, mutect2, varscan2
- TWF2 | c.1024C>T p.P342S | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.589); catalogued as COSV100564437; called by muse, mutect2, varscan2
- UBQLN3 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.332); catalogued as COSV61164275; called by muse, mutect2, varscan2
- UGT2A1 | c.829G>A p.G277R | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54141816; called by muse, mutect2
- UGT2B4 | c.9G>A p.M3I | Missense Mutation (SNP) | VAF 56/239 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV59317445; called by muse, mutect2, varscan2
- UGT2B7 | c.1229G>A p.G410E | Missense Mutation (SNP) | VAF 47/255 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59443616; called by muse, mutect2, varscan2
- UMOD | c.1570C>T p.Q524* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as COSV56775919; called by muse, mutect2
- UNC13C | c.1271C>T p.S424F | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs752573977, COSV52874767; called by muse, mutect2, varscan2
- USH2A | c.3649G>A p.D1217N | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs202247801, COSV56323471, COSV56334875, COSV56376283; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USH2A | c.2210G>A p.R737Q | Missense Mutation (SNP) | VAF 64/143 reads (45%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as rs778957703, COSV56336621; called by muse, mutect2, varscan2
- USP31 | c.2651C>T p.S884L | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.175); catalogued as COSV54852361; called by muse, mutect2, varscan2
- USP54 | c.3928C>T p.Q1310* | Nonsense Mutation (SNP) | VAF 17/95 reads (18%) | catalogued as COSV60442769; called by muse, mutect2, varscan2
- USPL1 | c.1304C>G p.A435G | Missense Mutation (SNP) | VAF 40/199 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV55000049, COSV55002409; called by muse, mutect2, varscan2
- VPS13A | c.6001C>T p.H2001Y | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs748687083, COSV62430324; called by muse, mutect2, varscan2
- VPS41 | c.2387C>T p.S796F | Missense Mutation (SNP) | VAF 27/242 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.133); catalogued as rs373217060; called by muse, mutect2, varscan2
- VPS50 | c.2825C>T p.S942F | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as COSV59918679; called by muse, mutect2, varscan2
- VWA8 | c.4111G>A p.V1371I | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs779018182, COSV64996549; called by muse, mutect2, varscan2
- WDR24 | c.223G>A p.G75S (on ENST00000248142; = p.G13S on NM_032259.4) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); catalogued as rs1307496100, COSV50197648, COSV99556533; called by muse, mutect2, varscan2
- WDR33 | c.3352C>T p.P1118S | Missense Mutation (SNP) | VAF 50/205 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.968); catalogued as COSV59249168; called by muse, mutect2, varscan2
- WHRN | c.1955C>A p.A652D | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV54330799; called by muse, mutect2, varscan2
- XDH | c.323G>A p.S108N | Missense Mutation (SNP) | VAF 39/162 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV65148819; called by muse, mutect2, varscan2
- XIRP1 | c.5008C>T p.P1670S | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs976977762, COSV61138610; called by muse, mutect2, varscan2
- XIRP2 | c.6790G>A p.D2264N (on ENST00000628543; = p.D2439N on NM_152381.6) | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs563915541, COSV54679859; called by muse, mutect2, varscan2
- YTHDF1 | c.655A>T p.N219Y | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV64832937; called by muse, mutect2, varscan2
- ZBTB10 | c.1635A>T p.E545D | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as COSV66947548; called by muse, mutect2, varscan2
- ZC3H3 | c.2147C>T p.P716L | Missense Mutation (SNP) | VAF 54/104 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as rs754043561, COSV52790002, COSV52790053; called by muse, mutect2, varscan2
- ZDBF2 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV65626249; called by muse, mutect2, varscan2
- ZFX | c.2278T>G p.S760A | Missense Mutation (SNP) | VAF 69/156 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); catalogued as COSV58447681; called by muse, mutect2, varscan2
- ZNF331 | c.219T>A p.D73E | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53476931; called by muse, mutect2, varscan2
- ZNF445 | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV68538917; called by muse, mutect2, varscan2
- ZNF490 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 63/169 reads (37%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV61008114; called by muse, mutect2, varscan2
- ZNF573 | c.871G>A p.E291K (on ENST00000536220 / NM_001172692.1; = p.E233K on NM_152360.3) | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.683); catalogued as COSV59825495; called by muse, mutect2, varscan2
- ZNF585A | c.1490C>T p.S497F (on ENST00000292841 / NM_001288800.2; = p.S442F on NM_152655.3) | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV53063891, COSV53067568; called by muse, mutect2, varscan2
- ZNF646 | c.2521C>T p.P841S | Missense Mutation (SNP) | VAF 47/228 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.066); catalogued as COSV54924383; called by muse, mutect2, varscan2
- ZNF648 | c.1429C>T p.P477S | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs998227572, COSV60571043; called by muse, mutect2, varscan2
- ZNF808 | c.2117C>T p.P706L | Missense Mutation (SNP) | VAF 45/315 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1267141093, COSV63119978; called by muse, mutect2, varscan2
- ZNF836 | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV59083373; called by muse, mutect2, varscan2
- ANXA7 | c.728del p.L243* (on ENST00000372919 / NM_001320880.2; = p.L221* on NM_001156.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | called by mutect2, pindel, varscan2
- ARF3 | c.22_25del p.L8Sfs*4 | Frame Shift Del (DEL) | VAF 45/238 reads (19%) | called by mutect2, pindel*, varscan2
- CCL3L3 | c.52T>A p.C18S | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CFAP74 | c.1282_1287del p.L428_L429del | In Frame Del (DEL) | VAF 7/19 reads (37%) | called by mutect2, varscan2
- CNRIP1 | c.495A>T p.*165Cext*42 | Nonstop Mutation (SNP) | VAF 19/99 reads (19%) | called by muse, mutect2, varscan2
- DDX3X | c.541-5_542del p.X181_splice (on ENST00000399959; = p.X182_splice on NM_001356.5) | Splice Site (DEL) | VAF 14/38 reads (37%) | called by mutect2, pindel, varscan2
- FCGBP | c.3023G>A p.G1008E | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- IGHD | c.73G>A p.V25I | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- IGHV3-21 | c.306G>A p.M102I | Missense Mutation (SNP) | VAF 66/388 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.324); called by muse, varscan2
- KLHDC7B | c.1574C>T p.P525L (on ENST00000395676; = p.P1166L on NM_138433.5) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.437); called by muse, mutect2
- LAMC1 | c.3487del p.S1163Qfs*14 | Frame Shift Del (DEL) | VAF 20/202 reads (10%) | called by mutect2, pindel, varscan2
- OTX2 | c.468_471dup p.S158Hfs*30 (on ENST00000408990 / NM_172337.3; = p.S166Hfs*30 on NM_021728.4) | Frame Shift Ins (INS) | VAF 18/85 reads (21%) | called by mutect2, pindel, varscan2
- PLXND1 | c.4424C>T p.A1475V | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RPS6KA6 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- RYR3 | c.7160G>A p.G2387E (on ENST00000389232; = p.G2388E on NM_001036.6) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SSUH2 | c.972_983del p.K324_Y328delinsN | In Frame Del (DEL) | VAF 26/114 reads (23%) | called by mutect2, pindel, varscan2
- A2ML1 | c.3375G>A p.K1125= | Silent (SNP) | VAF 35/110 reads (32%) | catalogued as COSV55287745, COSV55291088; called by muse, mutect2, varscan2
- ABO | c.885C>T p.I295= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as rs782094726, COSV71743538; called by muse, mutect2, varscan2
- ACSL1 | c.1902C>T p.I634= | Silent (SNP) | VAF 48/244 reads (20%) | catalogued as COSV55662815; called by muse, mutect2, varscan2
- ACTG2 | c.57G>A p.K19= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV61828392; called by muse, mutect2, varscan2
- ACTL9 | c.1200G>A p.R400= | Silent (SNP) | VAF 39/137 reads (28%) | catalogued as rs782592349, COSV61005805; called by muse, mutect2, varscan2
- ADCY5 | c.3231C>T p.I1077= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as rs780459593, COSV59198230; called by muse, mutect2, varscan2
- ADRA2C | c.1332C>T p.F444= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV57467263; called by muse, mutect2, varscan2
- AGAP6 | c.1473C>T p.S491= (on ENST00000374056 / NM_001365867.1; = p.S514= on NM_001077665.2) | Silent (SNP) | VAF 79/285 reads (28%) | called by muse, mutect2, varscan2
- APBB1IP | c.1038G>A p.K346= | Silent (SNP) | VAF 39/116 reads (34%) | catalogued as rs1419658671, COSV66132584, COSV99058773; called by mutect2, varscan2
- APLP2 | c.1803C>T p.P601= | Silent (SNP) | VAF 33/102 reads (32%) | catalogued as COSV53840275; called by muse, mutect2, varscan2
- ARFGEF2 | c.3531C>T p.F1177= | Silent (SNP) | VAF 37/184 reads (20%) | catalogued as COSV64212444; called by muse, mutect2, varscan2
- ARHGAP22 | c.1293C>T p.S431= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV50943745; called by muse, mutect2, varscan2
- ASTN2 | c.1068G>A p.K356= | Silent (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2, varscan2
- ATP11C | c.1041C>T p.F347= | Silent (SNP) | VAF 37/69 reads (54%) | catalogued as COSV59564292; called by muse, mutect2, varscan2
- BSND | c.918C>T p.L306= | Silent (SNP) | VAF 15/96 reads (16%) | catalogued as COSV64870671; called by muse, mutect2, varscan2
- BTBD9 | c.1143C>T p.A381= | Silent (SNP) | VAF 34/138 reads (25%) | catalogued as COSV58426334; called by muse, mutect2, varscan2
- C2CD3 | c.894G>A p.K298= | Silent (SNP) | VAF 46/137 reads (34%) | catalogued as COSV58093318; called by muse, mutect2, varscan2
- C2orf16 | c.4038A>G p.Q1346= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV62675786; called by muse, mutect2, varscan2
- C9orf135 | c.63C>T p.I21= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as rs867663881, COSV65874608; called by muse, mutect2, varscan2
- CACNA1G | c.5670C>T p.F1890= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV61727912; called by muse, mutect2
- CACNA2D3 | c.1758G>A p.E586= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV55540471; called by muse, mutect2, varscan2
- CCDC60 | c.1431G>A p.V477= | Silent (SNP) | VAF 29/98 reads (30%) | catalogued as COSV59543297; called by muse, mutect2, varscan2
- CD1E | c.45G>A p.G15= | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as rs994306541, COSV63769919; called by muse, mutect2, varscan2
- CD6 | c.1623C>T p.N541= | Silent (SNP) | VAF 16/126 reads (13%) | catalogued as rs1165678758, COSV57838729; called by muse, mutect2, varscan2
- CDH13 | c.903C>T p.I301= | Silent (SNP) | VAF 27/92 reads (29%) | catalogued as rs377468582; called by muse, mutect2, varscan2
- CEACAM3 | c.318C>T p.S106= | Silent (SNP) | VAF 83/274 reads (30%) | catalogued as COSV55761649; called by muse, mutect2, varscan2
- CEL | c.642C>T p.F214= (on ENST00000673714; = p.F211= on NM_001807.6) | Silent (SNP) | VAF 49/137 reads (36%) | catalogued as rs762719603, COSV60827156; called by muse, mutect2, varscan2
- CLDN9 | c.489C>T p.S163= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV60910765, COSV60911229; called by muse, mutect2, varscan2
- CLEC18A | c.39C>T p.L13= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV99846971; called by mutect2, varscan2
- CNRIP1 | c.494G>A p.*165= | Silent (SNP) | VAF 19/98 reads (19%) | called by muse, mutect2, varscan2
- CNTNAP1 | c.597C>T p.F199= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as rs561659603, COSV52850705; called by muse, mutect2, varscan2
- COL11A2 | c.3732G>A p.Q1244= (on ENST00000341947 / NM_080680.3; = p.Q1137= on NM_080679.2) | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV59497239; called by muse, mutect2, varscan2
- COL16A1 | c.4089T>C p.P1363= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV54706333; called by muse, mutect2, varscan2
- COL2A1 | c.525T>C p.L175= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV61530846; called by mutect2, varscan2
- COQ8B | c.33G>A p.G11= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV54574978; called by muse, mutect2, varscan2
- CPE | c.600G>A p.V200= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as rs368903815; called by muse, mutect2, varscan2
- CSPG4 | c.144C>T p.D48= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV57895378; called by muse, mutect2, varscan2
- CUBN | c.3396C>A p.I1132= | Silent (SNP) | VAF 38/119 reads (32%) | catalogued as COSV64716276; called by muse, mutect2, varscan2
- CYP4A22 | c.222G>A p.R74= | Silent (SNP) | VAF 30/123 reads (24%) | catalogued as COSV53740301; called by muse, mutect2, varscan2
- DALRD3 | c.1611C>T p.L537= (on ENST00000341949 / NM_001009996.3; = p.L370= on NM_018114.5) | Silent (SNP) | VAF 44/135 reads (33%) | catalogued as COSV58245066; called by muse, mutect2, varscan2
- DCDC2 | c.1200C>T p.R400= | Silent (SNP) | VAF 51/130 reads (39%) | catalogued as COSV65828838; called by muse, mutect2, varscan2
- DEDD2 | c.525C>T p.A175= | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as COSV60142000; called by muse, mutect2, varscan2
- DHX16 | c.1626C>T p.F542= | Silent (SNP) | VAF 22/106 reads (21%) | catalogued as COSV64564049; called by muse, mutect2, varscan2
- DLL4 | c.1716G>A p.S572= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as rs779920596, COSV51062967, COSV99989616; called by muse, mutect2, varscan2
- DNAH5 | c.12111G>A p.E4037= | Silent (SNP) | VAF 29/104 reads (28%) | catalogued as rs771256143, COSV54226072; called by muse, mutect2, varscan2
- DNAH5 | c.3528C>T p.F1176= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as COSV54213093; called by muse, mutect2, varscan2
- DNAH8 | c.10800G>A p.E3600= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as COSV59436868, COSV59447129; called by muse, mutect2, varscan2
- DPY19L3 | c.1503C>T p.S501= | Silent (SNP) | VAF 42/229 reads (18%) | catalogued as COSV60476996; called by muse, mutect2, varscan2
- DSCAML1 | c.3060C>T p.I1020= (on ENST00000321322; = p.I960= on NM_020693.4) | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as COSV58391054; called by muse, mutect2, varscan2
- DSCAML1 | c.762C>T p.S254= (on ENST00000321322; = p.S194= on NM_020693.4) | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as COSV58391066; called by muse, mutect2, varscan2
- DUS1L | c.219C>T p.D73= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as COSV60784634; called by muse, mutect2, varscan2
- DYNC1H1 | c.12432C>T p.I4144= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as rs1567022785, COSV64137142; ClinVar: likely benign; called by muse, mutect2, varscan2
- ELL2 | c.912A>G p.E304= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as COSV52982657; called by muse, mutect2, varscan2
- ERAL1 | c.687C>T p.I229= | Silent (SNP) | VAF 33/144 reads (23%) | catalogued as COSV54739941; called by muse, mutect2, varscan2
- ERBB2 | c.2502C>T p.S834= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as rs1213511121, COSV54071028; called by muse, mutect2, varscan2
- FAM9C | c.252G>A p.R84= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as COSV61775565; called by muse, mutect2, varscan2
- FBXO31 | c.1110C>T p.V370= | Silent (SNP) | VAF 23/81 reads (28%) | catalogued as rs1329767926, COSV61148986; called by muse, mutect2, varscan2
- FCGBP | c.843G>A p.G281= | Silent (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- FDFT1 | c.669C>T p.D223= | Silent (SNP) | VAF 41/164 reads (25%) | catalogued as rs1399671566, COSV55042445; called by muse, mutect2, varscan2
- FILIP1 | c.3276C>T p.V1092= | Silent (SNP) | VAF 52/174 reads (30%) | catalogued as COSV52730109; called by muse, mutect2, varscan2
- FOCAD | c.4086T>C p.S1362= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as COSV58099434; called by muse, mutect2, varscan2
- FRMPD1 | c.1596G>A p.V532= | Silent (SNP) | VAF 38/135 reads (28%) | catalogued as rs763733777, COSV66700478; called by muse, mutect2, varscan2
- GP1BA | c.477C>T p.L159= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as rs1185631139, COSV56699536; called by muse, mutect2
- GPR148 | c.483C>T p.S161= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV59308303; called by muse, mutect2, varscan2
- GPR75 | c.903C>T p.S301= | Silent (SNP) | VAF 12/53 reads (23%) | called by muse, mutect2, varscan2
- GREM2 | c.399G>A p.V133= | Silent (SNP) | VAF 13/139 reads (9%) | catalogued as rs779023425, COSV58951268; called by muse, mutect2, varscan2
- GRIA4 | c.1941G>A p.T647= | Silent (SNP) | VAF 29/96 reads (30%) | catalogued as rs1423373922, COSV56897145; called by muse, mutect2, varscan2
- GRK4 | c.1632C>T p.T544= | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as COSV61669264; called by muse, mutect2, varscan2
- GTF3C5 | c.969C>T p.I323= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV59600005; called by muse, mutect2, varscan2
- HHATL | c.1395C>T p.F465= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as rs17852071, COSV55134636; called by muse, mutect2, varscan2
- HPS1 | c.246C>T p.V82= | Silent (SNP) | VAF 35/118 reads (30%) | catalogued as COSV57267977; called by muse, mutect2, varscan2
- HTR1F | c.375C>T p.I125= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as COSV60389768; called by muse, mutect2, varscan2
- HYPK | c.204A>G p.K68= | Silent (SNP) | VAF 23/89 reads (26%) | catalogued as rs748691830, COSV51039152; called by muse, mutect2, varscan2
- IFRD1 | c.1053T>C p.F351= | Silent (SNP) | VAF 64/264 reads (24%) | catalogued as rs1396798362, COSV50044172; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.90G>A p.V30= | Silent (SNP) | VAF 26/163 reads (16%) | catalogued as rs774667870; called by muse, mutect2, varscan2
- IL7R | c.813C>T p.I271= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as rs200468194, COSV57406641; called by muse, mutect2, varscan2
- IQSEC3 | c.2946G>A p.T982= (on ENST00000538872 / NM_001170738.2; = p.T679= on NM_015232.1) | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs370969836, COSV58285052; called by muse, mutect2, varscan2
- ITGA11 | c.1374C>T p.T458= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV100241164, COSV59877857; called by muse, mutect2, varscan2
- ITGA7 | c.2442G>A p.G814= (on ENST00000555728; = p.G770= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV57695440; called by muse, mutect2, varscan2
- ITLN1 | c.195C>T p.I65= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as rs1367054199, COSV58275168; called by muse, mutect2, varscan2
- KHDRBS3 | c.57C>T p.S19= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs147742474, COSV100878631; called by muse, mutect2
- KLHDC7B | c.1575C>T p.P525= (on ENST00000395676; = p.P1166= on NM_138433.5) | Silent (SNP) | VAF 8/42 reads (19%) | called by muse, mutect2
- KRT72 | c.651G>A p.V217= | Silent (SNP) | VAF 20/97 reads (21%) | catalogued as COSV53374444; called by muse, mutect2, varscan2
- LCE1F | c.81G>A p.P27= | Silent (SNP) | VAF 37/106 reads (35%) | catalogued as rs759179642, COSV57668723; called by muse, mutect2, varscan2
- LEPR | c.2220C>T p.I740= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as rs757501135, COSV60750793; called by muse, mutect2, varscan2
- LRBA | c.7866C>T p.V2622= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV63955898; called by muse, mutect2, varscan2
- LRP2 | c.12708C>T p.I4236= | Silent (SNP) | VAF 32/112 reads (29%) | catalogued as rs780236605, COSV55554172; called by muse, mutect2, varscan2
- LRRC7 | c.492C>T p.P164= (on ENST00000651989 / NM_001370785.2; = p.P131= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV50462254; called by muse, mutect2, varscan2
- LRRTM3 | c.504C>T p.S168= | Silent (SNP) | VAF 29/117 reads (25%) | catalogued as COSV63665757; called by muse, mutect2, varscan2
- LTBP2 | c.1293C>T p.I431= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as COSV56208410; called by muse, mutect2, varscan2
- MAGEC1 | c.2076C>T p.L692= | Silent (SNP) | VAF 21/40 reads (53%) | catalogued as COSV53573102; called by muse, mutect2, varscan2
- MAP3K21 | c.2787G>A p.R929= | Silent (SNP) | VAF 35/124 reads (28%) | catalogued as COSV64041704; called by muse, mutect2, varscan2
- MET | c.666G>A p.T222= | Silent (SNP) | VAF 274/432 reads (63%) | catalogued as rs1444020594, COSV59259674; called by muse, varscan2
- MTMR9 | c.519T>G p.L173= | Silent (SNP) | VAF 48/190 reads (25%) | called by muse, mutect2, varscan2
- MXRA5 | c.7986C>T p.P2662= | Silent (SNP) | VAF 28/52 reads (54%) | catalogued as rs1390562388, COSV54235747; called by muse, mutect2, varscan2
- MYH4 | c.2841G>A p.L947= | Silent (SNP) | VAF 83/400 reads (21%) | catalogued as COSV55118517; called by muse, mutect2, varscan2
- MYO5A | c.2041C>T p.L681= | Silent (SNP) | VAF 29/102 reads (28%) | catalogued as COSV62560428; called by muse, mutect2, varscan2
- MYO7B | c.1731C>T p.I577= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV67347944, COSV67352665; called by muse, varscan2
- NCF4 | c.828G>A p.R276= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV50622275; called by muse, mutect2, varscan2
- NEXN | c.93A>G p.V31= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV53943059; called by muse, mutect2, varscan2
- NFASC | c.2235G>A p.E745= (on ENST00000339876 / NM_001378329.1; = p.E741= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV58365931; called by muse, mutect2
- NPC1 | c.525C>T p.L175= | Silent (SNP) | VAF 36/163 reads (22%) | called by muse, mutect2, varscan2
- NRIP1 | c.1374T>A p.V458= | Silent (SNP) | VAF 24/134 reads (18%) | catalogued as COSV59657510; called by muse, mutect2, varscan2
- NRXN3 | c.489G>A p.E163= (on ENST00000557594 / NM_001272020.2; = p.E795= on NM_004796.6) | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs1239733158, COSV55328846; called by muse, mutect2, varscan2
- NUP210 | c.2101C>A p.R701= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as rs762952679, COSV54406597; called by muse, mutect2, varscan2
- OR1S1 | c.924G>A p.K308= | Silent (SNP) | VAF 40/187 reads (21%) | catalogued as rs769014860, COSV58707143; called by muse, mutect2, varscan2
- OR2Y1 | c.471G>A p.L157= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as COSV100322918, COSV57136614; called by muse, mutect2, varscan2
- OR3A2 | c.870C>T p.I290= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV68695088; called by muse, mutect2, varscan2
- OR4B1 | c.190C>T p.L64= | Silent (SNP) | VAF 33/191 reads (17%) | catalogued as COSV58882916; called by muse, mutect2, varscan2
- OR51D1 | c.702C>T p.I234= | Silent (SNP) | VAF 36/112 reads (32%) | catalogued as COSV62914224; called by muse, mutect2, varscan2
- OR51I1 | c.912G>T p.G304= | Silent (SNP) | VAF 25/112 reads (22%) | catalogued as COSV66507949, COSV66509606; called by muse, mutect2, varscan2
- OR5AK2 | c.675C>T p.I225= | Silent (SNP) | VAF 42/152 reads (28%) | catalogued as rs1450758386, COSV58804520; called by muse, mutect2, varscan2
- OR6A2 | c.213G>A p.E71= | Silent (SNP) | VAF 30/115 reads (26%) | catalogued as COSV60264982; called by muse, mutect2, varscan2
- PAK2 | c.1410C>T p.S470= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as COSV59081371; called by muse, mutect2, varscan2
- PARD3B | c.3177C>T p.L1059= (on ENST00000406610 / NM_001302769.2; = p.L990= on NM_057177.7) | Silent (SNP) | VAF 44/167 reads (26%) | catalogued as COSV62512216; called by muse, mutect2, varscan2
- PCDH18 | c.2253C>T p.S751= | Silent (SNP) | VAF 34/91 reads (37%) | catalogued as rs998424915, COSV61268560; called by muse, mutect2, varscan2
- PCDHA5 | c.201C>T p.S67= | Silent (SNP) | VAF 56/172 reads (33%) | catalogued as COSV65352569; called by muse, mutect2, varscan2
- PCDHB13 | c.1497C>T p.P499= | Silent (SNP) | VAF 75/198 reads (38%) | catalogued as COSV53396780; called by muse, mutect2, varscan2
- PCDHB2 | c.1182C>T p.F394= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV50575103; called by muse, varscan2
- PDGFRL | c.129G>A p.K43= | Silent (SNP) | VAF 45/142 reads (32%) | catalogued as COSV52412314; called by muse, mutect2, varscan2
- PLCB2 | c.243C>T p.L81= | Silent (SNP) | VAF 13/56 reads (23%) | called by muse, mutect2, varscan2
- PLXND1 | c.4425C>T p.A1475= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as rs189832202, COSV60714695; called by muse, mutect2, varscan2
- PNMA8B | c.1593G>A p.R531= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV66536696; called by muse, mutect2
- POU1F1 | c.462G>A p.G154= | Silent (SNP) | VAF 20/124 reads (16%) | catalogued as rs1038788343, COSV60155986; called by muse, mutect2, varscan2
- PPP1R26 | c.1167C>T p.P389= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV63354789, COSV63355644; called by muse, mutect2, varscan2
- PRKACG | c.349C>T p.L117= | Silent (SNP) | VAF 24/101 reads (24%) | catalogued as COSV55248374; called by muse, mutect2, varscan2
- PRKG2 | c.1815G>A p.Q605= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as rs767945000, COSV52323116; called by muse, mutect2, varscan2
- PROKR2 | c.672C>T p.F224= | Silent (SNP) | VAF 46/100 reads (46%) | catalogued as rs760512876, COSV54086743; called by muse, mutect2, varscan2
- PTH2R | c.237G>A p.G79= | Silent (SNP) | VAF 20/81 reads (25%) | catalogued as COSV55916287; called by muse, mutect2, varscan2
- R3HDM1 | c.2265C>T p.F755= | Silent (SNP) | VAF 26/138 reads (19%) | catalogued as COSV51525000; called by muse, mutect2, varscan2
- RABGAP1 | c.3183C>T p.T1061= | Silent (SNP) | VAF 20/113 reads (18%) | catalogued as rs777756753, COSV65380143; called by muse, mutect2, varscan2
- RAPGEF3 | c.1956G>A p.V652= (on ENST00000389212; = p.V610= on NM_006105.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs940966561, COSV50207206; called by muse, mutect2, varscan2
- RBM47 | c.471G>A p.G157= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as COSV55935341; called by muse, mutect2, varscan2
- RBP3 | c.726C>T p.I242= | Silent (SNP) | VAF 20/42 reads (48%) | called by muse, mutect2, varscan2
- RCC1L | c.870C>T p.T290= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as rs1460969618; called by muse, mutect2, varscan2
- RECK | c.741C>T p.I247= | Silent (SNP) | VAF 27/77 reads (35%) | catalogued as rs762437351, COSV65035440; called by muse, mutect2, varscan2
- RHBDF1 | c.240C>T p.T80= | Silent (SNP) | VAF 55/211 reads (26%) | catalogued as COSV51955656; called by muse, mutect2, varscan2
- RNF122 | c.448C>T p.L150= | Silent (SNP) | VAF 51/205 reads (25%) | catalogued as rs867483600, COSV56359350, COSV56360171; called by muse, mutect2, varscan2
- ROS1 | c.1587C>T p.I529= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as rs527529345, COSV63855460; called by muse, mutect2, varscan2
- RPL3 | c.306C>T p.F102= | Silent (SNP) | VAF 76/246 reads (31%) | catalogued as rs1569161687, COSV53365444; called by muse, mutect2, varscan2
- RTEL1 | c.621C>T p.C207= | Silent (SNP) | VAF 39/257 reads (15%) | catalogued as COSV58894299; called by muse, mutect2, varscan2
- SALL2 | c.2061C>T p.A687= | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as COSV58103483; called by muse, mutect2, varscan2
- SDK1 | c.2316G>A p.P772= | Silent (SNP) | VAF 174/333 reads (52%) | catalogued as rs375976550; called by muse, mutect2, varscan2
- SEPHS1 | c.150C>T p.F50= | Silent (SNP) | VAF 49/196 reads (25%) | called by muse, mutect2, varscan2
- SIGLEC5 | c.879C>T p.I293= | Silent (SNP) | VAF 19/88 reads (22%) | catalogued as rs767791474, COSV55779872; called by muse, mutect2, varscan2
- SLC13A3 | c.216C>T p.F72= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as COSV51711829; called by muse, mutect2
- SLC22A3 | c.627G>A p.V209= | Silent (SNP) | VAF 52/197 reads (26%) | catalogued as COSV51713528; called by muse, mutect2, varscan2
- SLC34A2 | c.1221C>T p.F407= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as rs146575036, COSV65941548; called by muse, mutect2, varscan2
- SLC6A19 | c.1605C>G p.R535= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV57251423, COSV57251734; called by muse, mutect2, varscan2
- SLC9A2 | c.1293C>T p.I431= | Silent (SNP) | VAF 32/143 reads (22%) | catalogued as COSV52132226; called by muse, mutect2, varscan2
- SMYD1 | c.1296C>T p.P432= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV70225197; called by muse, mutect2
- SORT1 | c.1464C>T p.V488= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV56666516; called by muse, mutect2, varscan2
- SP100 | c.2289C>T p.F763= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as COSV50980498, COSV50988876, COSV99893420; called by muse, mutect2, varscan2
- SP140 | c.612G>A p.K204= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV59450076; called by muse, mutect2, varscan2
- SPRY1 | c.813C>T p.L271= | Silent (SNP) | VAF 25/99 reads (25%) | catalogued as rs1299583055, COSV59338444; called by muse, mutect2, varscan2
- STK24 | c.441C>T p.L147= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as COSV64822960; called by muse, mutect2, varscan2
- STX1B | c.285C>T p.I95= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV53060990; called by mutect2, varscan2
- SUSD3 | c.606G>A p.V202= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as COSV64937253; called by muse, mutect2, varscan2
- SVEP1 | c.717G>A p.K239= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV100238250; called by muse, mutect2, varscan2
- SYNGR1 | c.9G>A p.G3= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV53368373; called by muse, mutect2
- SYT7 | c.669C>T p.V223= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as COSV55655910; called by muse, mutect2, varscan2
- TAS2R3 | c.279C>T p.N93= | Silent (SNP) | VAF 88/711 reads (12%) | catalogued as COSV56092043; called by muse, varscan2
- TBC1D8B | c.2608T>C p.L870= | Silent (SNP) | VAF 31/56 reads (55%) | catalogued as COSV52179075; called by muse, mutect2, varscan2
- TEPSIN | c.718C>T p.L240= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs763595844, COSV56142903; called by muse, mutect2, varscan2
- TES | c.159C>T p.V53= | Silent (SNP) | VAF 28/138 reads (20%) | catalogued as COSV64042449; called by muse, mutect2, varscan2
- TEX14 | c.375G>A p.P125= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as rs1315153371, COSV53617394, COSV53621319; called by muse, mutect2, varscan2
- TG | c.4251C>T p.F1417= | Silent (SNP) | VAF 48/90 reads (53%) | catalogued as COSV55076879; called by muse, mutect2, varscan2
- THADA | c.2160C>T p.H720= | Silent (SNP) | VAF 25/121 reads (21%) | catalogued as rs367559092; called by muse, mutect2, varscan2
- TMC2 | c.1269C>T p.I423= | Silent (SNP) | VAF 22/114 reads (19%) | catalogued as rs267605863, COSV62653040; called by muse, mutect2, varscan2
- TMC3 | c.657C>T p.I219= | Silent (SNP) | VAF 36/140 reads (26%) | catalogued as rs765900743, COSV63922048, COSV63924141; called by muse, mutect2, varscan2
- TMEM132A | c.1800C>T p.V600= (on ENST00000453848 / NM_178031.3; = p.V601= on NM_017870.4) | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV50006537; called by muse, mutect2, varscan2
- TMEM132D | c.2265C>T p.I755= | Silent (SNP) | VAF 28/120 reads (23%) | catalogued as COSV67160498; called by muse, mutect2, varscan2
- TMEM26 | c.903C>T p.L301= | Silent (SNP) | VAF 29/117 reads (25%) | catalogued as COSV53262279; called by muse, mutect2, varscan2
- TRAK2 | c.183C>T p.L61= | Silent (SNP) | VAF 25/124 reads (20%) | catalogued as COSV60272202; called by muse, mutect2, varscan2
- TRBV28 | c.81G>A p.S27= | Silent (SNP) | VAF 34/49 reads (69%) | catalogued as rs769394787; called by muse, varscan2
- TRBV28 | c.99G>A p.R33= | Silent (SNP) | VAF 8/52 reads (15%) | called by muse, varscan2
- TRIB1 | c.849C>T p.P283= | Silent (SNP) | VAF 70/120 reads (58%) | catalogued as COSV61334838; called by muse, mutect2, varscan2
- TRIM28 | c.1251A>C p.S417= | Silent (SNP) | VAF 15/124 reads (12%) | catalogued as COSV53400331; called by muse, mutect2, varscan2
- TRPM2 | c.1227C>T p.I409= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs748020968, COSV55969999; called by muse, mutect2, varscan2
- TSPOAP1 | c.5514G>A p.R1838= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV52108980; called by muse, mutect2, varscan2
- TTLL8 | c.1254C>T p.N418= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs778998656; called by mutect2, varscan2
- UPK3A | c.385C>T p.L129= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs988150652, COSV53414516; called by muse, mutect2, varscan2
- UQCRC2 | c.132A>G p.P44= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as COSV51672327; called by muse, mutect2, varscan2
- UXT | c.294C>T p.F98= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV60039481; called by muse, mutect2, varscan2
- VSTM2A | c.9G>A p.G3= | Silent (SNP) | VAF 66/129 reads (51%) | catalogued as COSV56493884, COSV56494333; called by muse, mutect2, varscan2
- WASF3 | c.873C>T p.A291= | Silent (SNP) | VAF 25/88 reads (28%) | catalogued as rs781305434, COSV58966191; called by muse, mutect2, varscan2
- WNK1 | c.6309C>T p.T2103= (on ENST00000315939 / NM_018979.4; = p.T1855= on NM_014823.3) | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV100265869, COSV60033798; called by muse, mutect2, varscan2
- XIRP2 | c.7008G>A p.R2336= (on ENST00000628543; = p.R2511= on NM_152381.6) | Silent (SNP) | VAF 20/116 reads (17%) | catalogued as COSV54701677; called by muse, mutect2, varscan2
- ZFYVE26 | c.3721C>A p.R1241= | Silent (SNP) | VAF 30/97 reads (31%) | catalogued as COSV61328709, COSV61329224; called by muse, mutect2, varscan2
- ZFYVE28 | c.2181C>T p.I727= | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as COSV52111364; called by muse, mutect2, varscan2
- ZNF438 | c.1347C>T p.S449= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as COSV59195396; called by muse, mutect2, varscan2
- ZNF646 | c.3738G>A p.K1246= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV54924395; called by muse, mutect2, varscan2
- ZNF669 | c.459C>T p.I153= | Silent (SNP) | VAF 85/195 reads (44%) | catalogued as rs766578013, COSV58537705; called by muse, mutect2, varscan2
- ZNF684 | c.522C>T p.F174= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV65519119; called by muse, mutect2, varscan2
- ZSWIM2 | c.1200G>A p.V400= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV54575596; called by muse, mutect2, varscan2
- ZSWIM8 | c.2415C>T p.P805= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as rs777450053, COSV67132583; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504092 G>T | 5'Flank (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498156 T>C | 5'Flank (SNP) | VAF 30/71 reads (42%) | catalogued as rs898666303; called by muse, mutect2, varscan2
- ARPP19P2 | n.311C>T | RNA (SNP) | VAF 30/104 reads (29%) | called by muse, mutect2, varscan2
- GLYATL1 | c.-120G>A | 5'UTR (SNP) | VAF 7/32 reads (22%) | catalogued as COSV55608900; called by muse, mutect2, varscan2
- ILF3 | c.*242G>A | 3'UTR (SNP) | VAF 10/28 reads (36%) | catalogued as COSV99139289, COSV99139932; called by muse, mutect2, varscan2
- MAP1LC3C | c.*2C>T | 3'UTR (SNP) | VAF 5/48 reads (10%) | catalogued as rs760152788, COSV100606358; called by mutect2, varscan2
- MARCHF1 | c.-322-85963G>A | Intron (SNP) | VAF 58/241 reads (24%) | catalogued as rs772575830, COSV72276536; called by muse, mutect2, varscan2
- OR2W5 | n.1196G>A | RNA (SNP) | VAF 14/125 reads (11%) | called by muse, mutect2, varscan2
- SSPOP | n.6691A>G | RNA (SNP) | VAF 24/38 reads (63%) | catalogued as rs1384790338, COSV50487578; called by muse, mutect2, varscan2
- TCP10L3 | n.2719+1129G>A | Intron (SNP) | VAF 12/81 reads (15%) | catalogued as rs866323733, COSV100833086, COSV64751012; called by muse, mutect2, varscan2
- TTBK2 | c.823-7601C>T | Intron (SNP) | VAF 18/53 reads (34%) | called by muse, mutect2, varscan2
- XIRP2 | c.*745G>A | 3'UTR (SNP) | VAF 11/46 reads (24%) | catalogued as rs1559049463, COSV99742113; called by muse, mutect2, varscan2
